Somatic mutation profile of tumor specimen TCGA-12-0821-01A (aliquot TCGA-12-0821-01A-01W-0424-08) from TCGA case TCGA-12-0821, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.8 years (22,949 days).
Specimen TCGA-12-0821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21245dd3-31e8-4f4c-adc7-00d13e122de0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0821-10A (Blood Derived Normal), aliquot TCGA-12-0821-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3aff228f-7ce7-42bc-a0a8-bb1e6279d16f

The open-access MAF lists 94 somatic variants for this specimen: 79 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 36, Missense Mutation 34, Silent 14, Nonsense Mutation 6, Splice Site 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSPG2 | c.1219dup p.Q407Pfs*62 | Frame Shift Ins (INS) | VAF 9/73 reads (12%) | catalogued as rs763945561; ClinVar: likely pathogenic; called by mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 54/376 reads (14%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AAAS | c.108dup p.D37Rfs*50 | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | catalogued as rs767120429; called by mutect2, pindel, varscan2
- AK5 | c.1579C>T p.P527S (on ENST00000354567 / NM_174858.3; = p.P501S on NM_012093.4) | Missense Mutation (SNP) | VAF 66/782 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV60973985; called by muse, mutect2
- AKAP9 | c.11307dup p.Q3770Afs*52 (on ENST00000359028; = p.Q3746Afs*52 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 40/330 reads (12%) | catalogued as rs747796926; called by mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 19/127 reads (15%) | catalogued as rs774148781; called by mutect2, varscan2
- ATP2A3 | c.1712dup p.R572Kfs*35 | Frame Shift Ins (INS) | VAF 10/75 reads (13%) | catalogued as rs779330933; called by mutect2, pindel, varscan2
- ATP8A2 | c.2789T>A p.I930N | Missense Mutation (SNP) | VAF 340/758 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54955424; called by muse, varscan2
- ATR | c.4411T>C p.W1471R | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV63387155; called by muse, mutect2, varscan2
- BFAR | c.763dup p.Q255Pfs*7 | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs781267226; called by mutect2, varscan2
- CCDC54 | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV53758818; called by muse, mutect2, varscan2
- CD1B | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs186845827, COSV100939217, COSV63804283; called by muse, mutect2, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | catalogued as rs760923345; called by mutect2, varscan2
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | catalogued as rs765496989; called by mutect2, varscan2
- CDHR2 | c.1147dup p.R383Pfs*6 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | catalogued as rs774414740; called by pindel, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 54/404 reads (13%) | catalogued as rs747299117; called by mutect2, varscan2
- CHST4 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368228807; called by muse, mutect2, varscan2
- CNTN3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 359/902 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367688857; called by muse, mutect2, varscan2
- COL4A2 | c.2651G>T p.G884V | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64625009; called by muse, mutect2, varscan2
- CRYGA | c.476dup p.A160Cfs*29 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs762650691; called by mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 95/824 reads (12%) | catalogued as rs767756120; called by mutect2, varscan2
- DDB1 | c.685dup p.A229Gfs*15 | Frame Shift Ins (INS) | VAF 26/189 reads (14%) | catalogued as rs757472327; called by mutect2, varscan2
- DRD5 | c.1004G>T p.C335F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58577977; called by muse, mutect2, varscan2
- EPHX1 | c.400dup p.Q134Pfs*26 | Frame Shift Ins (INS) | VAF 32/203 reads (16%) | catalogued as rs756407271; called by mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 86/636 reads (14%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FILIP1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs147080592; called by muse, mutect2, varscan2
- FLT1 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs372046832, COSV56729596; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 18/121 reads (15%) | catalogued as rs752075537; called by mutect2, varscan2
- GZMH | c.612dup p.P205Afs*5 | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | catalogued as rs770777921; called by pindel, varscan2
- INSRR | c.3470G>A p.R1157H | Missense Mutation (SNP) | VAF 295/638 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139192917; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 28/112 reads (25%) | catalogued as rs780982673; called by mutect2, varscan2
- KCNH5 | c.2890dup p.Q964Pfs*9 | Frame Shift Ins (INS) | VAF 16/126 reads (13%) | catalogued as rs35940222; called by mutect2, varscan2
- KIAA1549 | c.4427dup p.E1477Gfs*3 | Frame Shift Ins (INS) | VAF 8/63 reads (13%) | catalogued as rs752867430; called by mutect2, pindel, varscan2
- KLF3 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV54711059; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 43/246 reads (17%) | catalogued as rs757410385; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | catalogued as rs777328830; called by mutect2, varscan2
- MCOLN3 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62014488; called by muse, mutect2, varscan2
- MCTP2 | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59144890; called by muse, mutect2, varscan2
- MUC17 | c.12334G>A p.A4112T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs751624526, COSV60290633; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 39/166 reads (23%) | catalogued as rs754860965; called by mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 20/124 reads (16%) | catalogued as rs780417788; called by mutect2, varscan2
- NXF3 | c.338G>C p.W113S | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67703754; called by muse, mutect2, varscan2
- OGA | c.1929T>G p.Y643* | Nonsense Mutation (SNP) | VAF 32/43 reads (74%) | catalogued as COSV63381991; called by muse, mutect2, varscan2
- OR10R2 | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63768756; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 33/258 reads (13%) | catalogued as rs780916980; called by mutect2, varscan2
- OXSR1 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 126/250 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV61258959; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 294/2376 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3CA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 106/121 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV55935970; called by muse, mutect2, varscan2
- PPP1R3A | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as COSV52884132; called by muse, mutect2, varscan2
- PRKCZ | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs75260030; called by muse, mutect2
- PSD4 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs201700173, COSV55525638; called by muse, mutect2, varscan2
- QSER1 | c.1876C>G p.L626V (on ENST00000399302; = p.L755V on NM_001076786.3) | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV67900732; called by muse, mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 18/120 reads (15%) | catalogued as rs756557178; called by mutect2, varscan2
- RARRES1 | c.277A>C p.I93L | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs201288879, COSV52962749; called by muse, mutect2
- SALL4 | c.2983dup p.V995Gfs*16 | Frame Shift Ins (INS) | VAF 18/135 reads (13%) | catalogued as rs753320334; called by mutect2, varscan2
- SCN9A | c.4856G>A p.R1619Q (on ENST00000303354; = p.R1608Q on NM_002977.3) | Missense Mutation (SNP) | VAF 229/614 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142201175, COSV57612198; called by muse, mutect2, varscan2
- SERPINA1 | c.491C>A p.S164* | Nonsense Mutation (SNP) | VAF 110/429 reads (26%) | catalogued as COSV63345748; called by muse, mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 62/334 reads (19%) | catalogued as rs746556543; called by mutect2, varscan2
- SLC6A18 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777600288; called by muse, mutect2
- SLC7A2 | c.1909G>A p.A637T (on ENST00000494857 / NM_001370338.1; = p.A676T on NM_003046.6) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV50255448; called by muse, mutect2, varscan2
- SSH2 | c.2756dup p.E920Rfs*22 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | catalogued as rs752567808; called by mutect2, varscan2
- STAG2 | c.462+2T>C p.X154_splice | Splice Site (SNP) | VAF 33/41 reads (80%) | catalogued as COSV54360217; called by muse, mutect2, varscan2
- TAGLN3 | c.141dup p.G48Rfs*21 | Frame Shift Ins (INS) | VAF 7/69 reads (10%) | catalogued as rs762583525; called by mutect2, pindel, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 78/422 reads (18%) | catalogued as rs763321097; called by mutect2, varscan2
- TEPSIN | c.1501dup p.Q501Pfs*53 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | catalogued as rs756562081; called by pindel, varscan2
- TNFRSF8 | c.616T>A p.S206T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV55796985; called by muse, mutect2
- TSPAN16 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 98/271 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1189304873, COSV57441952, COSV57442423; called by muse, mutect2, varscan2
- UBXN11 | c.1273G>A p.A425T (on ENST00000374221 / NM_183008.2; = p.A392T on NM_145345.2) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1381314574; called by mutect2, varscan2
- WDR44 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 232/266 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV54160134, COSV54170626; called by muse, mutect2, varscan2
- WDR6 | c.2421dup p.R808Afs*3 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | catalogued as rs750038548; called by mutect2, varscan2
- ZCCHC14 | c.973-2A>C p.X325_splice (on ENST00000268616; = p.X462_splice on NM_015144.3) | Splice Site (SNP) | VAF 59/151 reads (39%) | catalogued as COSV51886741; called by muse, mutect2, varscan2
- ZFYVE26 | c.4599G>A p.W1533* | Nonsense Mutation (SNP) | VAF 584/797 reads (73%) | catalogued as COSV61329272; called by muse, mutect2, varscan2
- ZNRF3 | c.733C>T p.R245* (on ENST00000544604 / NM_001206998.2; = p.R145* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 36/51 reads (71%) | catalogued as rs1188411932, COSV60431282; called by muse, mutect2, varscan2
- DKK1 | c.659G>A p.C220Y | Missense Mutation (SNP) | VAF 58/682 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SHBG | c.522dup p.L175Afs*39 | Frame Shift Ins (INS) | VAF 7/77 reads (9%) | called by mutect2, pindel
- SKIV2L | c.1409T>G p.L470R | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2
- TMEM201 | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- VIRMA | c.1751G>C p.S584T | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- ZNF26 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ALOX15 | c.384G>C p.R128= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV53398207, COSV53401364; called by muse, mutect2, varscan2
- ANGPT1 | c.1218A>G p.K406= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as COSV52442389; called by muse, mutect2, varscan2
- ATAD1 | c.333C>T p.I111= | Silent (SNP) | VAF 85/99 reads (86%) | catalogued as COSV57757042; called by muse, mutect2, varscan2
- BRAF | c.1914T>A p.A638= (on ENST00000288602 / NM_001374244.1; = p.A598= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 39/180 reads (22%) | catalogued as COSV56203004; called by muse, mutect2, varscan2
- CD14 | c.852G>A p.S284= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV57370840; called by muse, mutect2, varscan2
- CNKSR1 | c.1677G>A p.Q559= (on ENST00000374253 / NM_001297647.2; = p.Q552= on NM_006314.3) | Silent (SNP) | VAF 78/99 reads (79%) | catalogued as COSV58793455; called by muse, mutect2, varscan2
- DCTN1 | c.2973C>T p.I991= | Silent (SNP) | VAF 241/593 reads (41%) | catalogued as rs140969689, COSV62619536, COSV62619647; called by muse, mutect2, varscan2
- FLT1 | c.1080G>A p.K360= | Silent (SNP) | VAF 249/501 reads (50%) | catalogued as rs755860865, COSV56729610, COSV99146772; called by muse, mutect2, varscan2
- GPR4 | c.453G>A p.A151= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs759854339, COSV59917243; called by muse, mutect2, varscan2
- JMJD1C | c.2703C>T p.P901= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- LRRIQ1 | c.1731T>C p.D577= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV67831826; called by muse, mutect2, varscan2
- TMEM106B | c.420T>G p.R140= | Silent (SNP) | VAF 94/1249 reads (8%) | catalogued as rs140753733; called by muse, mutect2
- WWC1 | c.2538G>A p.E846= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as COSV54651892; called by muse, mutect2, varscan2
- ZSWIM5 | c.873C>T p.H291= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as COSV62734579; called by muse, mutect2, varscan2
- NDUFB1 | chr14:92121760 G>C | 5'Flank (SNP) | VAF 11/21 reads (52%) | catalogued as rs968978334, COSV54098670; called by muse, mutect2, varscan2
